Somatic mutation profile of tumor specimen TCGA-17-Z001-01A (aliquot TCGA-17-Z001-01A-01W-0746-08) from TCGA case TCGA-17-Z001, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z001-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4afb459-8fc1-4b3e-95fe-5dbf41009fff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z001-11A (Solid Tissue Normal), aliquot TCGA-17-Z001-11A-01W-0746-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/182b62f5-d632-41ed-ac95-e35492481e0f

The open-access MAF lists 214 somatic variants for this specimen: 165 protein-altering or splice-affecting, 47 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 138, Silent 47, Nonsense Mutation 11, Splice Site 6, Frame Shift Del 4, Splice Region 2, In Frame Del 2, Frame Shift Ins 2, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 18/56 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730881999, COSV52666031, COSV52675881, COSV52731113, COSV52828604; ClinVar: uncertain significance / likely pathogenic; called by muse, varscan2
- ABCC12 | c.551G>A p.W184* | Nonsense Mutation (SNP) | VAF 29/215 reads (13%) | catalogued as rs763797025; called by muse, varscan2
- ABCG8 | c.120C>G p.Y40* | Nonsense Mutation (SNP) | VAF 12/64 reads (19%) | catalogued as rs1000291485; called by muse, mutect2
- ADNP | c.191C>G p.T64R | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.957); catalogued as COSV62424636; called by muse, mutect2, varscan2
- ADRB3 | c.403C>A p.R135S | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771506959; called by muse, varscan2
- APC | c.4580C>T p.P1527L | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.996); catalogued as rs747209080, COSV57376003, COSV57391217; called by muse, mutect2, varscan2
- ARHGAP21 | c.1096G>A p.V366M | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.054); catalogued as rs763063260; called by muse, mutect2, varscan2
- CCDC150 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as rs1013398446; called by muse, mutect2, varscan2
- CDCA2 | c.1651G>A p.A551T | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.022); catalogued as rs371866632; called by muse, mutect2, varscan2
- CLVS2 | c.378G>A p.W126* | Nonsense Mutation (SNP) | VAF 20/84 reads (24%) | catalogued as COSV51568515; called by muse, mutect2, varscan2
- CNTNAP5 | c.2416A>G p.T806A | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs186713620; called by muse, mutect2, varscan2
- CPN1 | c.983G>T p.R328L | Missense Mutation (SNP) | VAF 35/281 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV64942186; called by muse, mutect2, varscan2
- CSMD1 | c.8789G>A p.G2930E (on ENST00000520002; = p.G2929E on NM_033225.6) | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100155191; called by muse, mutect2, varscan2
- CYP26A1 | c.1366A>G p.T456A | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1183293057; called by muse, mutect2, varscan2
- DST | c.4110del p.M1370Ifs*7 (on ENST00000361203 / NM_001374722.1; = p.M1044Ifs*7 on NM_001723.6) | Frame Shift Del (DEL) | VAF 7/45 reads (16%) | catalogued as COSV99755705; called by mutect2, pindel, varscan2
- FAM135B | c.720G>C p.W240C | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52711980, COSV52755617; called by muse, mutect2, varscan2
- FOXP2 | c.810G>T p.W270C | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1224336230; called by muse, mutect2, varscan2
- GALNT17 | c.1093G>A p.G365R | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751701264, COSV100351740; called by muse, varscan2
- GAP43 | c.455C>G p.P152R | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as CM122681, COSV59345430; called by muse, mutect2, varscan2
- GBP5 | c.658C>G p.P220A | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.461); catalogued as COSV58591276; called by muse, mutect2, varscan2
- HOOK3 | c.1081G>T p.A361S | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.92); catalogued as rs1431367409; called by muse, mutect2, varscan2
- HOXA3 | c.1235del p.P412Rfs*92 | Frame Shift Del (DEL) | VAF 19/63 reads (30%) | catalogued as COSV57826565; called by mutect2, varscan2
- KCNA4 | c.846G>C p.R282S | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as COSV60255940; called by muse, mutect2, varscan2
- KEAP1 | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1379198956; called by muse, varscan2
- L1CAM | c.1894C>A p.R632S | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.218); catalogued as COSV62826709, COSV62827874; called by muse, mutect2
- LRFN5 | c.359G>T p.S120I | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.179); catalogued as COSV99985859; called by muse, mutect2, varscan2
- LRP1B | c.9400G>T p.D3134Y | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.87); catalogued as COSV67285900; called by muse, mutect2
- LY9 | c.587C>A p.P196H | Missense Mutation (SNP) | VAF 47/203 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.738); catalogued as COSV54437137; called by muse, mutect2, varscan2
- MAGEB18 | c.897C>A p.F299L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.416); catalogued as COSV57464250; called by muse, mutect2
- MARCHF10 | c.1507G>A p.G503R | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.904); catalogued as COSV60885420; called by muse, mutect2, varscan2
- MED12L | c.3304G>A p.V1102I | Missense Mutation (SNP) | VAF 77/168 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs376411623; called by muse, mutect2, varscan2
- MTRR | c.694G>A p.E232K (on ENST00000264668; = p.E205K on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV104391200; called by muse, mutect2, varscan2
- MUC17 | c.2308A>C p.T770P | Missense Mutation (SNP) | VAF 25/284 reads (9%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.484); catalogued as COSV60296820; called by muse, mutect2
- MXRA5 | c.5667G>T p.K1889N | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54228193; called by muse, mutect2, varscan2
- MYH8 | c.3442_3444del p.E1148del | In Frame Del (DEL) | VAF 46/117 reads (39%) | catalogued as rs1191926786; called by pindel, varscan2
- MYO1D | c.206G>T p.R69L | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100554111; called by muse, mutect2, varscan2
- MYO7B | c.6119C>A p.P2040H | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1307370293, COSV61442224; called by muse, mutect2, varscan2
- NLGN4X | c.841G>T p.G281C | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52004121, COSV99321427; called by muse, mutect2
- NRXN1 | c.3113C>G p.S1038C | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV58491317; called by muse, mutect2, varscan2
- OR5W2 | c.774G>A p.M258I | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as COSV60618837; called by muse, mutect2, varscan2
- PHF3 | c.2981A>G p.N994S | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs187803576; called by muse, mutect2, varscan2
- PIK3R6 | c.1444G>T p.G482C | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1414607474; called by muse, mutect2, varscan2
- PRR5 | c.764A>T p.Y255F (on ENST00000336985 / NM_181333.4; = p.Y246F on NM_015366.4) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.73); catalogued as rs1203115581; called by muse, mutect2, varscan2
- PRUNE2 | c.5189C>A p.A1730D | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.028); catalogued as COSV100944607; called by muse, mutect2, varscan2
- PTPRB | c.4302C>A p.S1434R | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764803235; called by muse, mutect2, varscan2
- RBP3 | c.1912G>A p.A638T | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs782708494; called by muse, mutect2
- RGL3 | c.1960C>T p.P654S | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs1361272789; called by muse, mutect2, varscan2
- ROBO2 | c.73C>A p.R25S | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1356551506, COSV100165806; called by muse, mutect2, varscan2
- RP2 | c.342C>A p.C114* | Nonsense Mutation (SNP) | VAF 10/100 reads (10%) | catalogued as COSV54461157; called by muse, mutect2
- RYR2 | c.12944G>T p.G4315V | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63658108, COSV63667834; called by muse, mutect2, varscan2
- SASH1 | c.727A>G p.N243D | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.978); catalogued as rs775158503; called by muse, mutect2, varscan2
- SEC23IP | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as rs201464386; called by muse, mutect2, varscan2
- SEMA5A | c.1298G>A p.R433Q | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.303); catalogued as rs138343991, COSV66790750; called by muse, mutect2, varscan2
- SERPINB5 | c.843G>T p.M281I | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1295212797; called by muse, mutect2
- SLC35F4 | c.1271C>A p.T424K (on ENST00000339762 / NM_001352015.2; = p.T388K on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1490774842; called by muse, mutect2
- SPATA19 | c.88G>T p.V30F | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV54484428; called by muse, mutect2, varscan2
- SPHKAP | c.1925C>T p.S642F | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV60893734; called by muse, mutect2, varscan2
- SPTAN1 | c.2591A>G p.K864R | Missense Mutation (SNP) | VAF 49/162 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as rs769130912; called by muse, mutect2, varscan2
- SPTBN5 | c.9497G>T p.R3166M | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs1435142300; called by muse, mutect2, varscan2
- TBX22 | c.651G>T p.M217I | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV100960767, COSV64786067; called by muse, mutect2, varscan2
- UGT2B10 | c.699G>C p.Q233H | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs1306435232; called by muse, mutect2, varscan2
- WDPCP | c.916G>A p.V306I | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs761751600, COSV55418868; called by muse, mutect2, varscan2
- WDTC1 | c.421G>T p.A141S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1396798168; called by muse, mutect2, varscan2
- WNT2B | c.125+1G>T p.X42_splice | Splice Site (SNP) | VAF 4/15 reads (27%) | catalogued as rs565788658; called by muse, mutect2, varscan2
- ZC3H12B | c.1447G>C p.G483R | Missense Mutation (SNP) | VAF 27/304 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.303); catalogued as COSV100161570; called by muse, mutect2
- ZNF382 | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1345033874, COSV99497744; called by muse, mutect2, varscan2
- ZNF804A | c.298G>T p.A100S | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs766073072, COSV56435615; called by muse, mutect2, varscan2
- AADAC | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- ACKR3 | c.274T>A p.W92R | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- AHNAK2 | c.3479A>T p.D1160V | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- AIFM1 | c.1577C>A p.T526N | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.077); called by muse, mutect2
- ALMS1 | c.12462G>T p.K4154N | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- ALPK2 | c.367A>T p.R123W | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.221); called by muse, mutect2
- BIRC6 | c.3300G>T p.M1100I | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- BMP15 | c.556A>G p.I186V | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C4orf19 | c.33C>T p.S11= | Splice Region (SNP) | VAF 44/222 reads (20%) | called by muse, mutect2, varscan2
- CBLL2 | c.529C>A p.L177I | Missense Mutation (SNP) | VAF 29/278 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CCDC136 | c.1729G>T p.E577* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
- CDC42BPA | c.508G>T p.E170* | Nonsense Mutation (SNP) | VAF 19/52 reads (37%) | called by muse, mutect2, varscan2
- CDH18 | c.768C>G p.I256M | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- CFAP46 | c.5627G>T p.G1876V | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- CHRM1 | c.860C>A p.S287Y | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- CREG2 | c.683C>A p.S228Y | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- CRHBP | c.423T>G p.C141W | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSMD3 | c.6241G>T p.G2081* (on ENST00000297405 / NM_001363185.1; = p.G1977* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 14/55 reads (25%) | called by muse, mutect2, varscan2
- CTNND2 | c.1680G>T p.Q560H | Missense Mutation (SNP) | VAF 54/220 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- DISP3 | c.2519G>T p.G840V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- DLG2 | c.1982G>A p.G661E | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.15); called by muse, varscan2
- DUOX2 | c.3996C>A p.H1332Q | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- DYNC1H1 | c.7083G>C p.M2361I | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- EDIL3 | c.371A>C p.E124A | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.97); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- EGF | c.2350G>T p.D784Y | Missense Mutation (SNP) | VAF 52/196 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.112); called by muse, mutect2
- EPHA5 | c.954C>G p.S318R | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.146); called by muse, mutect2
- EVC2 | c.2332G>T p.E778* | Nonsense Mutation (SNP) | VAF 38/104 reads (37%) | called by mutect2, varscan2
- EXOC4 | c.1099G>T p.V367L | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FBN2 | c.6128G>T p.C2043F | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FMN2 | c.5072C>A p.A1691D | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FPR2 | c.551G>T p.G184V | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- FRMPD4 | c.1151C>T p.S384L | Missense Mutation (SNP) | VAF 7/192 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.312); called by muse, mutect2
- GABRB3 | c.392dup p.H132Afs*15 | Frame Shift Ins (INS) | VAF 30/134 reads (22%) | called by mutect2, varscan2
- GABRB3 | c.390dup p.V131Cfs*16 | Frame Shift Ins (INS) | VAF 24/158 reads (15%) | called by mutect2*, pindel, varscan2*
- GEM | c.649T>C p.F217L | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- GPR84 | c.1016A>G p.N339S | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRIK2 | c.2562+1G>A p.X854_splice | Splice Site (SNP) | VAF 7/92 reads (8%) | called by muse, mutect2
- GRM1 | c.92G>C p.G31A | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); called by muse, varscan2
- HOXD8 | c.523C>A p.H175N | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- IGHV3-38 | c.91G>T p.V31L | Missense Mutation (SNP) | VAF 57/228 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.14); called by mutect2, varscan2
- IGKV2D-24 | c.338G>T p.C113F | Missense Mutation (SNP) | VAF 62/276 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGSF9 | c.242A>T p.Y81F | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- IL1RAPL1 | c.312G>T p.W104C | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IPCEF1 | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.014); called by muse, varscan2
- ITGA8 | c.359G>T p.R120I | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- JAG1 | c.2932C>T p.H978Y | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- KIF21A | c.3059G>C p.G1020A (on ENST00000361418 / NM_001378440.1; = p.G1007A on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- LAMA2 | c.3325T>A p.F1109I | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.051); called by muse, mutect2
- LRRTM3 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MAMLD1 | c.1378C>A p.P460T | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MCM10 | c.1946C>A p.P649Q (on ENST00000484800 / NM_182751.3; = p.P648Q on NM_018518.5) | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MMP8 | c.1268A>C p.K423T | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- MTTP | c.1798A>G p.M600V | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- MUC17 | c.9160A>G p.S3054G | Missense Mutation (SNP) | VAF 51/194 reads (26%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- NALCN | c.3934T>C p.F1312L | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- NR1H3 | c.94G>T p.A32S | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); called by muse, mutect2
- NRAP | c.5008C>G p.P1670A (on ENST00000359988 / NM_001322945.2; = p.P1635A on NM_006175.4) | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OGA | c.2353G>T p.D785Y | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PCDH11X | c.3178G>T p.G1060C | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by mutect2, varscan2
- PCDHGA2 | c.1349C>G p.P450R | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLCL2 | c.3007A>T p.T1003S (on ENST00000615277 / NM_001144382.2; = p.T877S on NM_015184.5) | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.011); called by mutect2, varscan2
- PPP3CA | c.1439_1459del p.N480_R486del | In Frame Del (DEL) | VAF 33/165 reads (20%) | called by mutect2, pindel, varscan2
- PRUNE1 | c.616C>G p.P206A | Missense Mutation (SNP) | VAF 35/228 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- PSG1 | c.554A>T p.Q185L | Missense Mutation (SNP) | VAF 180/495 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- RAB11FIP1 | c.1073C>T p.T358I | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2
- RANBP2 | c.3889A>T p.K1297* | Nonsense Mutation (SNP) | VAF 23/74 reads (31%) | called by muse, mutect2, varscan2
- RERE | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2
- RP2 | c.343C>A p.Q115K | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); called by muse, mutect2
- RTL5 | c.952C>A p.P318T | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- SCAF4 | c.697C>T p.Q233* | Nonsense Mutation (SNP) | VAF 18/62 reads (29%) | called by muse, mutect2, varscan2
- SDR42E1 | c.137C>G p.T46S | Missense Mutation (SNP) | VAF 37/244 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SEMA6C | c.1434-1G>T p.X478_splice | Splice Site (SNP) | VAF 23/69 reads (33%) | called by muse, mutect2, varscan2
- SERPINB4 | c.1097A>G p.N366S | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- SH3TC1 | c.576T>A p.H192Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SIGLEC6 | c.1045G>T p.G349* | Nonsense Mutation (SNP) | VAF 19/56 reads (34%) | called by muse, mutect2, varscan2
- SIRT2 | c.660G>T p.K220N | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- SLC24A5 | c.387T>C p.G129= | Splice Region (SNP) | VAF 16/90 reads (18%) | called by muse, mutect2, varscan2
- SLC2A12 | c.136A>T p.T46S | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- SLIT3 | c.2977T>A p.C993S | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SMARCA1 | c.469C>G p.L157V | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- SNRNP40 | c.904G>T p.A302S | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- SYNE1 | c.3453G>T p.K1151N (on ENST00000367255 / NM_182961.4; = p.K1158N on NM_033071.3) | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); called by muse, mutect2
- TBC1D31 | c.2068C>G p.Q690E | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TECR | c.383+2dup p.X128_splice | Splice Site (INS) | VAF 22/77 reads (29%) | called by mutect2, pindel, varscan2
- TECTA | c.2561C>T p.A854V | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- TRDV2 | c.83A>G p.Q28R | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- UNC45B | c.1488C>G p.D496E | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- UPF1 | c.2297A>T p.E766V (on ENST00000599848 / NM_001297549.2; = p.E755V on NM_002911.4) | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- URB2 | c.2183G>T p.G728V | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- USP33 | c.442del p.Q148Rfs*11 | Frame Shift Del (DEL) | VAF 11/62 reads (18%) | called by mutect2, pindel, varscan2
- XYLT1 | c.961A>T p.M321L | Missense Mutation (SNP) | VAF 88/278 reads (32%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, varscan2
- ZAN | c.2621C>A p.P874H | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ZNF157 | c.998G>T p.G333V | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZNF276 | c.1475-9_1475del p.X492_splice (on ENST00000443381 / NM_001113525.2; = p.X417_splice on NM_152287.4) | Splice Site (DEL) | VAF 12/48 reads (25%) | called by mutect2, pindel, varscan2
- ZNF285 | c.211C>G p.L71V | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- ZNF485 | c.1203G>C p.Q401H | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.187); called by muse, varscan2
- ZNF746 | c.324+1G>A p.X108_splice | Splice Site (SNP) | VAF 58/224 reads (26%) | called by muse, varscan2
- ZSCAN1 | c.1016del p.G339Afs*111 | Frame Shift Del (DEL) | VAF 15/41 reads (37%) | called by mutect2, pindel, varscan2
- ABCC11 | c.3846G>A p.E1282= | Silent (SNP) | VAF 51/305 reads (17%) | called by muse, mutect2, varscan2
- ACO1 | c.2106T>C p.T702= | Silent (SNP) | VAF 6/56 reads (11%) | called by muse, mutect2, varscan2
- AFF2 | c.744G>A p.A248= | Silent (SNP) | VAF 26/444 reads (6%) | catalogued as rs782235447, COSV60657039; called by muse, mutect2
- ANGEL1 | c.1242G>T p.V414= | Silent (SNP) | VAF 18/63 reads (29%) | called by muse, mutect2, varscan2
- APOB | c.1263C>G p.P421= | Silent (SNP) | VAF 39/141 reads (28%) | called by muse, mutect2, varscan2
- ASB17 | c.391C>T p.L131= | Silent (SNP) | VAF 9/34 reads (26%) | called by muse, mutect2, varscan2
- BRDT | c.1911G>A p.L637= | Silent (SNP) | VAF 15/87 reads (17%) | called by muse, mutect2, varscan2
- CCR1 | c.762C>A p.P254= | Silent (SNP) | VAF 22/92 reads (24%) | called by muse, mutect2, varscan2
- CDH9 | c.2109T>A p.T703= | Silent (SNP) | VAF 22/100 reads (22%) | catalogued as COSV50308990; called by muse, mutect2, varscan2
- CFLAR | c.498A>G p.T166= | Silent (SNP) | VAF 23/89 reads (26%) | called by muse, mutect2, varscan2
- CHST1 | c.1161C>T p.I387= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as rs985096921, COSV57323051; called by muse, mutect2
- DCST1 | c.270G>T p.G90= | Silent (SNP) | VAF 10/130 reads (8%) | called by muse, mutect2
- DYNC2H1 | c.8871G>A p.K2957= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs1247271935, COSV62088613; called by muse, mutect2, varscan2
- FKBP6 | c.834A>G p.R278= | Silent (SNP) | VAF 42/191 reads (22%) | called by muse, mutect2, varscan2
- FOXK1 | c.1713C>T p.P571= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs774571574; called by mutect2, varscan2
- GALNT16 | c.699C>A p.T233= | Silent (SNP) | VAF 34/173 reads (20%) | catalogued as rs751469391; called by muse, varscan2
- GP2 | c.1101C>T p.Y367= (on ENST00000381362 / NM_001007240.3; = p.Y364= on NM_001502.4) | Silent (SNP) | VAF 80/365 reads (22%) | catalogued as rs766379727; called by muse, mutect2, varscan2
- HRNR | c.2208A>T p.S736= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV100913863; called by muse, mutect2, varscan2
- IGHV3-35 | c.153T>C p.S51= | Silent (SNP) | VAF 52/775 reads (7%) | called by muse, mutect2
- JCAD | c.3441C>A p.G1147= | Silent (SNP) | VAF 37/159 reads (23%) | called by muse, mutect2, varscan2
- KCNA2 | c.1302C>T p.S434= | Silent (SNP) | VAF 14/76 reads (18%) | called by muse, mutect2, varscan2
- KRTAP13-1 | c.420G>T p.L140= | Silent (SNP) | VAF 12/44 reads (27%) | called by muse, mutect2, varscan2
- LRP1 | c.12204C>T p.V4068= | Silent (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2, varscan2
- LRP1B | c.4251C>A p.I1417= | Silent (SNP) | VAF 22/84 reads (26%) | called by muse, mutect2, varscan2
- LRRC4C | c.1230G>T p.T410= | Silent (SNP) | VAF 20/167 reads (12%) | catalogued as COSV53436862; called by muse, mutect2, varscan2
- MAGEB4 | c.49C>A p.R17= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as rs148486223; called by muse, mutect2, varscan2
- MCOLN1 | c.909G>T p.V303= | Silent (SNP) | VAF 16/37 reads (43%) | called by muse, mutect2, varscan2
- MEOX1 | c.240C>A p.I80= | Silent (SNP) | VAF 7/43 reads (16%) | called by mutect2, varscan2
- MYH2 | c.3930C>A p.G1310= | Silent (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- MYH7B | c.2299C>A p.R767= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs370220364; called by mutect2, varscan2
- NOTCH2 | c.4707G>T p.L1569= | Silent (SNP) | VAF 15/55 reads (27%) | called by muse, mutect2, varscan2
- OR7A17 | c.405C>A p.I135= | Silent (SNP) | VAF 40/109 reads (37%) | catalogued as rs1407610364, COSV100541561; called by muse, mutect2, varscan2
- PHKA2 | c.3240C>A p.V1080= | Silent (SNP) | VAF 8/57 reads (14%) | called by muse, mutect2, varscan2
- PLAT | c.85C>A p.R29= | Silent (SNP) | VAF 28/103 reads (27%) | catalogued as COSV54275393; called by muse, varscan2
- PRAME | c.1290C>A p.L430= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV101287285; called by mutect2, varscan2
- PRICKLE2 | c.624C>A p.G208= (on ENST00000295902; = p.G152= on NM_198859.4) | Silent (SNP) | VAF 8/43 reads (19%) | called by muse, mutect2, varscan2
- PRPS1 | c.351T>A p.S117= | Silent (SNP) | VAF 15/133 reads (11%) | called by muse, mutect2, varscan2
- PRSS1 | c.696C>T p.V232= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as COSV100298509; called by muse, varscan2
- SLC22A14 | c.1218C>T p.G406= | Silent (SNP) | VAF 24/141 reads (17%) | catalogued as rs960190037, COSV56197637; called by muse, mutect2, varscan2
- STPG2 | c.1056G>T p.A352= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as rs149484886; called by muse, mutect2, varscan2
- TIE1 | c.1143G>A p.V381= | Silent (SNP) | VAF 27/126 reads (21%) | called by muse, mutect2, varscan2
- TMEM132A | c.1227G>A p.V409= (on ENST00000453848 / NM_178031.3; = p.V410= on NM_017870.4) | Silent (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2, varscan2
- TMEM8B | c.1320G>T p.R440= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV65077496; called by muse, varscan2
- TRPC6 | c.478C>A p.R160= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as COSV60259652; called by muse, mutect2, varscan2
- VIT | c.1929C>T p.P643= (on ENST00000389975 / NM_001177969.1; = p.P658= on NM_053276.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as rs765056539; called by muse, mutect2, varscan2
- XPO7 | c.2970C>T p.I990= | Silent (SNP) | VAF 9/21 reads (43%) | called by muse, mutect2, varscan2
- ZDHHC11 | c.600G>T p.G200= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV52072688; called by muse, mutect2, varscan2
- DCHS2 | n.5241C>A | RNA (SNP) | VAF 14/74 reads (19%) | called by muse, mutect2, varscan2
- MYCBPAP | c.-1C>T | 5'UTR (SNP) | VAF 8/21 reads (38%) | catalogued as rs1398593231; called by muse, mutect2, varscan2
